TCGA case TCGA-12-0829 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97094aed-69f7-4f4e-a87e-533979e11514

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Dead; Days to death: 626 days (1.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 75.2 years (27,471 days); Year of diagnosis: 2006; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 64 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 64 days; Number of cycles: 1; Treatment dose: 75 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 95 days; Days to treatment end: 473 days (1.3 years); Number of cycles: 6; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Clinical Trial; Treatment intent type: Adjuvant; Days to treatment start: 115 days; Days to treatment end: 473 days (1.3 years); Treatment dose: 1 mL.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 474 days (1.3 years); Days to treatment end: 571 days (1.6 years); Treatment dose: 10 mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 474 days (1.3 years); Days to treatment end: 571 days (1.6 years); Number of cycles: 4; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 572 days (1.6 years); Days to treatment end: 599 days (1.6 years); Treatment dose: 10 mg/kg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 572 days (1.6 years); Days to treatment end: 599 days (1.6 years); Number of cycles: 1; Treatment dose: 125 mg/m2; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 76.5 years (27,944 days); Days to diagnosis: 473 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 467 days (1.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 473 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 473 days (1.3 years).
- Days to follow up: 626 days (1.7 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-12-0829-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
  Slide TCGA-12-0829-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0; Percent lymphocyte infiltration: 0.
- Sample TCGA-12-0829-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0829-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temador; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: CPT-11; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Attac.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 626 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 626 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 473 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0829-01A-01D-0384-01): tumor purity 0.42, ploidy 2.05, whole-genome doublings 0.
